RC case RC-B5DA — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ec0a5113-131c-4b74-95d1-3e606b14333e

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1978; Vital status: Alive; Country of birth: El Salvador.

Diagnoses (2)
1. T-cell large granular lymphocytic leukemia (the primary disease): ICD-O-3 morphology code: 9831/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 37.0 years (13,520 days); Year of diagnosis: 2015; Method of diagnosis: Blood Draw; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): Low Risk; Sites of involvement: Peripheral blood.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Ruxolitinib; Days to treatment start: 2,248 days (6.2 years); Treatment outcome: Treatment Ongoing; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Organ Transplantation.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response; Timepoint category: Postoperative.
   Recorded as not given: adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, NOS.
2. Progression of the blood (histology not recorded by GDC). Age at diagnosis: 43.0 years (15,692 days); Days to diagnosis: 2,172 days (5.9 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Treatment Ongoing.

Follow-up (3 entries)
- Day 2,172 (progression): Progression or recurrence: Yes; Progression or recurrence anatomic site: Blood; Days to progression: 2,172 days (5.9 years).
- Days to follow up: 2,201 days (6.0 years); Disease response: With Tumor.
- Days to follow up: 2,528 days (6.9 years); Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 1.

Molecular and laboratory tests
- Lactate Dehydrogenase 179 U/L [Blood test normal range upper: 220].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Organ Transplant (Site) / Depression.
- Timepoint category: Follow-up; Comorbidities: Headache / Depression / Sleep Apnea / Polycythemia.
- Timepoint category: Initial Diagnosis; Weight: 67 kg; Height: 177.5 cm; BMI: 21.3.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 1; Tobacco smoking onset year: 1996; Tobacco smoking quit year: 2008.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B5DA-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B5DA-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
  Slide RC-B5DA-TBP1-A-1-0-CS2: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 10; Percent necrosis: 90; Percent stromal cells: 0; Percent lymphocyte infiltration: 90; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 5.
